Somatic mutation profile of tumor specimen 0DRRU2 from CCDI case PBCHAP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.8 years (5,388 days).
Specimen 0DRRU2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2cf575-1247-4f5e-be51-450e791a82c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRRTU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43e84d2-3c01-4b08-8fa0-6b97d1faf24d

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 397/986 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 532/1201 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.527dup p.L177Tfs*40 | Frame Shift Ins (INS) | VAF 87/284 reads (31%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3728G>C p.R1243P | Missense Mutation (SNP) | VAF 233/490 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100757983, COSV60796547, COSV60801666; called by muse, mutect2, varscan2
- DTNA | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 485/1187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004060; called by muse, mutect2, varscan2
- TENM4 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 214/474 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs566743822; called by muse, varscan2
- IRF2BP1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MIS18BP1 | c.2113G>A p.G705S | Missense Mutation (SNP) | VAF 455/1038 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RASAL2 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 704/1584 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTSL2 | c.468C>T p.D156= | Silent (SNP) | VAF 262/607 reads (43%) | catalogued as rs746513236, COSV100618882; called by muse, mutect2, varscan2
- FUT4 | c.1590G>C p.R530= | Silent (SNP) | VAF 143/347 reads (41%) | called by muse, mutect2, varscan2
- OTUD4 | c.2769C>A p.L923= (on ENST00000447906 / NM_001366057.1; = p.L858= on NM_001102653.1) | Silent (SNP) | VAF 436/1078 reads (40%) | catalogued as COSV71381842; called by mutect2, varscan2
- ARMCX4 | c.1039-4193A>G | Intron (SNP) | VAF 282/652 reads (43%) | called by muse, varscan2
- MKLN1 | c.*95T>A | 3'UTR (SNP) | VAF 158/345 reads (46%) | called by muse, mutect2, varscan2
- PFKL | c.747+62G>A | Intron (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2
- S100B | c.-1-34G>T | Intron (SNP) | VAF 107/223 reads (48%) | called by muse, mutect2
- SAMD8 | c.*64C>T | 3'UTR (SNP) | VAF 110/221 reads (50%) | catalogued as rs990370468, COSV65509145; called by muse, mutect2, varscan2
- SKIV2L | c.2859-56G>T | Intron (SNP) | VAF 40/44 reads (91%) | called by muse, mutect2, varscan2
